Somatic mutation profile of tumor specimen 0DOG3C from CCDI case PBCBAR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.9 years (6,556 days).
Specimen 0DOG3C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30d0c9ca-aa15-42f6-9878-18e2d860c47e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOG2T (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0428acd5-e631-46f9-80b3-fb5f07a48b3b

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Nonsense Mutation 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/602 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- IGSF22 | c.2320C>T p.R774* (on ENST00000319338; = p.R875* on NM_173588.4) | Nonsense Mutation (SNP) | VAF 81/413 reads (20%) | catalogued as rs776372705; called by muse, mutect2, varscan2
- MPDZ | c.2975C>T p.A992V | Missense Mutation (SNP) | VAF 52/662 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs1228989405; called by muse, mutect2
- ZNF638 | c.5018A>G p.D1673G | Missense Mutation (SNP) | VAF 23/517 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- C2CD2 | c.-54G>C | 5'UTR (SNP) | VAF 3/25 reads (12%) | catalogued as rs1035573493; called by muse, varscan2
- HMGB1 | c.*85T>C | 3'UTR (SNP) | VAF 6/96 reads (6%) | catalogued as COSV100360835; called by muse, mutect2
